Gene-level copy-number profile of tumor specimen TCGA-UY-A9PH-01A from TCGA case TCGA-UY-A9PH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 73.0 years (26,654 days).
Specimen TCGA-UY-A9PH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.8e21f2cf-ba0f-4118-97a8-275c2fc76155.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A9PH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d7136f12-ee84-45dc-a11c-224da97b0020

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 11; copy number 2: 11,141; copy number 3: 23,469; copy number 4: 22,392; copy number 5: 673; copy number 6: 1,749; copy number 7: 58; copy number 9: 38; copy number 10: 22; copy number 11: 45; copy number 12: 2; copy number 13: 5; copy number 15: 35; copy number 17: 57; copy number 26: 18; copy number 30: 50; copy number 32: 3; copy number 35: 12; copy number 37: 4; copy number 38: 20; copy number 40: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A9PH-01A-11D-A38F-01): tumor purity 0.44, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–3): MTAP, AL359922.1.
- chr9:21,892,188–22,128,103, 9 genes (within-gene range 0–3): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 372 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,739,057–161,470,523, 50 genes, copy number 30: SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, AL831711.1.
- chr1:162,316,852–167,022,214, 89 genes, copy number 13–38 (broad region; genes not listed).
- chr1:185,157,080–185,291,781, 1 gene, copy number 11 (within-gene range 3–11): SWT1.
- chr1:185,226,808–186,190,949, 18 genes, copy number 11 (within-gene range 3–11): RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1.
- chr1:186,521,773–186,581,191, 3 genes, copy number 32: AL096803.3, AL096803.1, AL096803.2.
- chr1:186,680,622–188,242,678, 13 genes, copy number 11: PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1.
- chr11:69,371,463–69,926,813, 15 genes, copy number 7–11: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.
- chr11:70,078,302–71,252,577, 24 genes, copy number 10–17 (within-gene range 4–17): ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:79,402,022–79,612,300, 3 genes, copy number 9–12: MIR708, MIR5579, AP001978.1.
- chr11:82,603,529–82,643,445, 1 gene, copy number 9 (within-gene range 5–9): AP000793.1.
- chr12:38,532,895–38,907,430, 3 genes, copy number 40 (within-gene range 2–40): AC087897.1, AC087897.2, CPNE8.
- chr12:50,392,383–52,223,813, 60 genes, copy number 10–37 (within-gene range 4–37): LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80, LINC02874.
- chr12:54,058,254–54,687,434, 36 genes, copy number 9: FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1.
- chr19:37,884,823–39,032,785, 56 genes, copy number 7: WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
